Gene-level copy-number profile of tumor specimen ALCH-B1LU-TTP1-A from ALCHEMIST case ALCH-B1LU, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Non-small cell carcinoma; Age at diagnosis: 79.8 years (29,140 days).
Specimen ALCH-B1LU-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e822dd4f-5066-4238-969b-27e0ff3112a5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1LU-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,218 have no estimate.
https://portal.gdc.cancer.gov/files/8ecce6d4-bdaa-4841-a60c-b6bf2f2cbebd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 80; copy number 2: 58,195; copy number 3: 127; copy number 8: 3.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:66,721,158–66,745,929, 3 genes, copy number 8: ATP5F1AP10, SDR42E1P4, FKBP4P8.

Autosomal genes at a single copy (total copy number 1): 80. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
